Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A194, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A194-01A (Primary Tumor).

100-0-3

Melanoma, NOS 8720/3 12/14/10 lw

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Melanoma left shoulder.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Excision melanoma left shoulder, sentinel node biopsy left axilla.

Site code: Shoulder - Subcutaneous tissue C49.1

FINAL DIAGNOSIS:

PART 1: SKIN AND SUBCUTANEOUS TISSUE, WIDE EXCISION LEFT SHOULDER -

- A. MALIGNANT MELANOMA, 4.2 CM WITH FOCAL SUPERFICIAL ULCERATION AND SURFACE ACUTE INFLAMMATION, NODULAR AND EXOPHYTIC.
- B. MARGINS OF RESECTION FREE OF NEOPLASM BUT DEEP MARGIN CLOSE (0.1 CM).

PART 2: LYMPH NODE, SENTINEL #1, AXILLA, EXCISION -

BENIGN TWO (2) LYMPH NODES, NEGATIVE FOR METASTATIC MELANOMA OR MALIGNANCY (0/2) (see comment).

PART 3: SOFT TISSUE, DEEP MARGIN, LEFT SHOULDER, EXCISION -

FIBROUS AND FATTY TISSUE, NEGATIVE FOR MALIGNANT MELANOMA OR MELANOCYTIC LESION.

PART 4: LYMPH NODE, SENTINEL #2, AXILLA, EXCISION -

BENIGN ONE (1) LYMPH NODE, NEGATIVE FOR METASTATIC MELANOMA OR MALIGNANCY (0/1) (see comment).

COMMENT:

Parts 2 and 4 are also examined using immunoperoxidase stains Tyrosinase, S100, Melan A, HMB-45 and CD68. The melanoma markers are negative. CD68 is positive in macrophages. This confirms the above diagnosis.

Source: NCI Genomic Data Commons file 663c13ee-96fe-435e-b562-c240189c44bc (TCGA-ER-A194.76553A5D-46A4-48C4-947D-1CE09B486987.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).